Somatic mutation profile of tumor specimen TARGET-40-0A4I0U-01A (aliquot TARGET-40-0A4I0U-01A-01D) from TARGET case TARGET-40-0A4I0U, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 39.9 years (14,570 days).
Specimen TARGET-40-0A4I0U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72a72b32-1e45-43d4-a628-78de4d6bc540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I0U-10A (Blood Derived Normal), aliquot TARGET-40-0A4I0U-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46aae508-d40d-451a-820d-bcae9ad89fa6

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Del 4, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2LI1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV53183490; called by muse, mutect2
- FGF9 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as rs1426446815; called by muse, varscan2
- GRIA2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs1359410555, COSV52395082, COSV99642740; called by muse, mutect2
- HIVEP1 | c.7409G>A p.G2470D | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867914667; called by muse, mutect2
- C2CD2 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ETV4 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRTAP19-4 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LMTK2 | c.4387C>T p.P1463S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2
- MAP3K10 | c.532del p.R178Gfs*5 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.2361C>A p.N787K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- NTAN1 | c.274_275del p.H92Lfs*2 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- OR6P1 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- OVCH1 | c.3150del p.K1050Nfs*2 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- PLEKHH2 | c.1648del p.W550Gfs*8 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- SMARCD3 | c.1258G>A p.V420I (on ENST00000262188 / NM_001003801.2; = p.V407I on NM_003078.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCER1 | c.648G>A p.A216= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as rs1295769498, COSV62646310; called by muse, mutect2
- OR2T34 | c.312C>T p.I104= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs955076364; called by mutect2, varscan2
- PTGER3 | c.1113C>A p.S371= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- ZNF425 | c.783C>T p.L261= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1454020101, COSV65200927; called by muse, mutect2
- FAM71E1 | c.-16del | 5'UTR (DEL) | VAF 3/23 reads (13%) | called by pindel, varscan2
- TGFB1I1 | c.326-69C>G | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
